Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6354, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6354-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

- A. APICAL TISSUE
- B. PROSTATE

SPECIMEN(S):

- A. APICAL TISSUE
- B. PROSTATE

GROSS DESCRIPTION:

A. APICAL TISSUE

Received in formalin is an unoriented tan pink soft tissue fragment 0.5 x 0.4 x 0.4 cm. Toto A1.

B. PROSTATE

Received fresh labeled with the patient identification and designated as "Part B, Prostate" is a 47g resected prostate 5.0 cm from right to left, 4.2 cm from anterior to posterior, and 3.0 cm from apex to base, with attached right and left seminal vesicles and vas deferens. The capsule is tan pink smooth and intact. The specimen is inked as follows: Anterior-Orange, Posterior-Black, Apex-Red, Base-Blue, Right-Green, Left-Yellow. After removal of the apex and base, the remaining prostate weight is 23g. The specimen is serially sectioned from apex to base to reveal firm tan fibrous parenchyma. No obvious lesions or nodules are grossly identified. The attached right and left seminal vesicles are 4.0 x 2.5 x 2.0 cm and 5.5 x 1.0 x 1.0 cm, respectively, are sectioned to beige tan cystic tissue with no gross evidence of tumor involvement. The attached right and left segments of vas deferens are 6.0 x 0.4 cm and 1.0 x 0.5 cm, respectively, are sectioned to reveal firm tan tubular structure with no gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (Levels I and III). The remainder of the specimen is submitted as follows:

- B1: right apex
- B2-B3: left apex
- B4: Level I right anterior capsule
- B5: Level I right posterior capsule
- B6: Level I left anterior capsule
- B7: Level I left posterior capsule
- B8: Level II right anterior
- B9: Level II right posterior
- B10: Level II left anterior
- B11-B12: Level II left posterior
- B13: Level III right anterior capsule
- B14: Level III right posterior capsule
- B15: Level III left anterior capsule
- B16: Level III left posterior capsule
- B17: right base with periurethral margin
- B18: left base with periurethral margin
- B19: right base
- B20: left base
- B21: right base
- B22: left base
- B23: right seminal vesicle and vas deferens
- B24-B25: left seminal vesicle and vas deferens

DIAGNOSIS:

A. SOFT TISSUE, APICAL, RESECTION:

- NO PROSTATIC GLANDS IDENTIFIED.

B. PROSTATE, PROSTATECTOMY:

- ADENOCARCINOMA, CONVENTIONAL TYPE.
- GLEASON'S GRADE 3+4 = 7/10.
- COMPRISING APPROXIMATELY 10% OF THE GLAND.
- MULTIFOCAL, INVOLVING BOTH THE APEX AND POSTERIOR LATERAL RIGHT LOBE.
- NO EXTRAPROSTATIC EXTENSION IDENTIFIED.
- NO SEMINAL VESICLE INVASION IDENTIFIED.
- ALL MARGINS ARE NEGATIVE FOR TUMOR.
- NO ANGIOLYMPHATIC INVASION IDENTIFIED.
- PERINEURAL INVASION IS PRESENT IN THE RIGHT LOBE.

[page 2 of 3]
[REDACTED]

- HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: B: PROSTATE

Location: Right

Posterior lateral

Apical

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 10%

Gleason Grade/Sum:: Grade 3 + 4 , Sum 7

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: No

Bladder Neck Involved: No

Margins Involvement: No

Frozen Performed: No

Lymph Nodes: No lymph nodes sampled

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 2b N X M X

CLINICAL HISTORY:

Prostate cancer.

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer.

ADDENDUM:

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block [REDACTED]

Population: seminal vesicle stroma

Stain/Marker:Result: Comment:

CONGO RED STAIN Positive For amyloid

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the [REDACTED] of the. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and negative controls.

[page 3 of 3]
INTERPRETATION: The stroma surrounding the glands in the left seminal vesicle demonstrate apple green birefringence on the Congo red stain. This is characteristic of amyloid. Clinical correlation is recommended.

Source: NCI Genomic Data Commons file 1d12bf7b-ae2c-45f1-b311-550ae527dc50 (TCGA-G9-6354.CFFC4C63-D738-41CD-8EE3-25C190A9638C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).